Surgical pathology report (de-identified scan), TCGA case TCGA-33-6737, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-6737-01A (Primary Tumor).

[page 1 of 2]
SURG PATH REPORT
COLLECTION DATE/TIME:

1st Specimen collected on
Accessioned on

FINAL DIAGNOSIS ----- Pathologist:

1. R4 LYMPH NODE (EXCISION): METASTATIC CARCINOMA INVOLVING 1 OF 1 LYMPH NODE (4 MM FOCUS).
2. HIGH R4 LYMPH NODE (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
3. R10 LYMPH NODE (EXCISION): METASTATIC CARCINOMA INVOLVING 1 OF 1 LYMPH NODE (4 MM FOCUS).
4. RIGHT LUNG UPPER LOBE (LOBECTOMY):

SPECIMEN TYPE:
Lobectomy

TUMOR SITE:
Right, upper lobe

HISTOLOGIC TYPE:
Adenosquamous carcinoma

TUMOR SIZE:
Greatest dimension: 7.5 cm

LOCATION, SIZE, AND HISTOLOGIC TYPE OR ADDITIONAL SEPARATE TUMOR NODULES, IF ANY:
None identified

HISTOLOGIC GRADE:
G3: Poorly differentiated

LYMPH NODES:
Metastatic carcinoma in 3 of 9 lymph nodes
(see part 1-6)

EXTENT OF INVASION (STAGING)
PRIMARY TUMOR:
pT2: Tumor which is >3 cm

REGIONAL LYMPH NODES:
pN2: Metastasis in ipsilateral mediastinal or subcarinal lymph nodes

DISTANT METASTASIS;
pMx: Cannot be assessed

MARGINS:
Margins uninvolved by invasive carcinoma

VENOUS/ARTERIAL (LARGE VESSEL) INVASION:
Indeterminate

LYMPHATIC (SMALL VESSEL) INVASION:
Present

ADDITIONAL PATHOLOGIC FINDINGS:
None identified

5. P3 LYMPH NODE (DISSECTION): TWO (2) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

6. STATION 7 LYMPH NODE (EXCISION): ONE (1) LYMPH NODE AND

[page 2 of 2]
ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

ADDENDUM ----- Pathologist:
EGFR MUTATION ANALYSIS:
RESULTS: No mutation detected.

K-RAS MUTATION ANALYSIS:
RESULTS: No mutations were identified at codons 12 and 13
of the KRAS gene.

NOTE: A copy of the complete report is available in and is on
file in the molecular pathology laboratory.

***** End of Diagnosis *****

Clinical History:
? LUNG CANCER

Source: NCI Genomic Data Commons file a2cd5eba-3e99-4a21-b536-2b7bad82802a (TCGA-33-6737.D8A5D5D4-48A9-4B5A-BF57-FF32E7302D74.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).